Somatic mutation profile of tumor specimen TCGA-AA-3529-01A (aliquot TCGA-AA-3529-01A-02D-1953-10) from TCGA case TCGA-AA-3529, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 78.3 years (28,609 days).
Specimen TCGA-AA-3529-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bcbb4fef-6af1-4302-b4c1-ac738321be6f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3529-11A (Solid Tissue Normal), aliquot TCGA-AA-3529-11A-01D-1554-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4a247ba9-9b66-45ed-acd4-a267967c8d38

The open-access MAF lists 21 somatic variants for this specimen: 9 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 10, Missense Mutation 8, 3'UTR 1, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAHD1 | c.882G>T p.Q294H | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.687); catalogued as COSV101346762; called by muse, mutect2, varscan2
- BCL2L10 | c.177T>G p.I59M | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.034); catalogued as COSV99548581; called by muse, mutect2
- CELSR1 | c.6902C>T p.P2301L | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs538530181, COSV53085254; called by muse, mutect2, varscan2
- GDF7 | c.1225G>A p.A409T | Missense Mutation (SNP) | VAF 50/179 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.49); catalogued as rs1212242798, COSV99693999; called by muse, mutect2, varscan2
- HDGFL1 | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs756221629, COSV100014587; called by muse, mutect2, varscan2
- PLPP7 | c.755G>A p.R252H | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.24); catalogued as rs757523015, COSV64841309; called by muse, mutect2, varscan2
- POLRMT | c.3176G>A p.R1059H | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.334); catalogued as rs1430372357, COSV99241858; called by muse, mutect2, varscan2
- SMOX | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as rs765116817, COSV53866167; called by muse, mutect2, varscan2
- ZNF816-ZNF321P | c.511C>T p.Q171* | Nonsense Mutation (SNP) | VAF 43/191 reads (23%) | catalogued as COSV100008374, COSV100008424; called by muse, mutect2, varscan2
- AHDC1 | c.1473C>A p.T491= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as COSV99899366; called by muse, mutect2, varscan2
- ASPHD1 | c.861C>T p.F287= | Silent (SNP) | VAF 18/85 reads (21%) | catalogued as rs968825927, COSV100435489, COSV58105023; called by muse, mutect2, varscan2
- GPR149 | c.1545G>A p.L515= | Silent (SNP) | VAF 83/293 reads (28%) | catalogued as COSV101078473; called by muse, mutect2, varscan2
- HELZ2 | c.1788C>T p.P596= (on ENST00000467148 / NM_001037335.2; = p.P27= on NM_033405.3) | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as rs942000586, COSV64409220, COSV64409347; called by muse, mutect2, varscan2
- MPP3 | c.402G>A p.S134= | Silent (SNP) | VAF 77/247 reads (31%) | catalogued as rs368175437, COSV68199085; called by muse, mutect2, varscan2
- MYO5C | c.1188C>T p.N396= | Silent (SNP) | VAF 134/413 reads (32%) | catalogued as rs560516622, COSV55903936; called by muse, mutect2, varscan2
- NOTCH1 | c.5805C>T p.A1935= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as rs774693459, COSV53078040, COSV99488420; ClinVar: likely benign; called by muse, mutect2, varscan2
- SSBP4 | c.465C>G p.G155= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs900725890, COSV99526110; called by muse, mutect2, varscan2
- SV2C | c.1083G>A p.K361= | Silent (SNP) | VAF 106/360 reads (29%) | catalogued as COSV100456280; called by muse, mutect2, varscan2
- VPS51 | c.2094G>A p.S698= | Silent (SNP) | VAF 34/151 reads (23%) | catalogued as rs1455503436, COSV54206322, COSV99659701; called by muse, mutect2, varscan2
- ATP6AP2 | c.-7C>T | 5'UTR (SNP) | VAF 4/15 reads (27%) | called by mutect2, varscan2
- XIRP2 | c.*206G>A | 3'UTR (SNP) | VAF 40/329 reads (12%) | catalogued as rs1394048203, COSV99743420; called by muse, mutect2, varscan2
